FM case AD1174 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/389bd26f-a5d0-4da8-9cde-d0e08669c655

Female, 77.2 years: Non-small cell carcinoma (ICD-O-3 8046/3) of the lung. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
